Somatic mutation profile of tumor specimen TCGA-4P-AA8J-01A (aliquot TCGA-4P-AA8J-01A-11D-A391-08) from TCGA case TCGA-4P-AA8J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.3 years (24,222 days).
Specimen TCGA-4P-AA8J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c70c1218-75ee-49f7-bd70-92c01edc8ca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4P-AA8J-10A (Blood Derived Normal), aliquot TCGA-4P-AA8J-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba6e0286-6bd9-404c-9050-da69bea3bc86

The open-access MAF lists 149 somatic variants for this specimen: 106 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 41, Nonsense Mutation 7, Frame Shift Ins 7, Splice Site 2, Intron 1, Frame Shift Del 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R5D | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs863225082, CM153575, COSV55150326; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6639C>G p.I2213M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101330137; called by muse, mutect2, varscan2
- ACTR6 | c.942dup p.K315* | Frame Shift Ins (INS) | VAF 16/76 reads (21%) | catalogued as rs1337709347; called by mutect2, varscan2
- ADAM10 | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99546451; called by muse, mutect2, varscan2
- ADAR | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs367899281; called by muse, mutect2, varscan2
- AKAP11 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160990993, COSV99214219; called by muse, mutect2, varscan2
- APPL2 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV99315032; called by muse, mutect2, varscan2
- ARPP21 | c.2325C>A p.N775K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99492811; called by muse, mutect2, varscan2
- ARSJ | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746575851, COSV59536553; called by muse, mutect2, varscan2
- ASB6 | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99475811; called by muse, mutect2, varscan2
- BAZ2A | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99467270; called by muse, mutect2, varscan2
- BAZ2B | c.4757C>A p.P1586H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV100600875, COSV58601510; called by muse, mutect2, varscan2
- BCHE | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV100012869, COSV99072218; called by muse, mutect2, varscan2
- CEMIP2 | c.3437C>G p.S1146C | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV100987471; called by muse, mutect2, varscan2
- CEP250 | c.7009G>A p.D2337N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61170823; called by muse, mutect2, varscan2
- CEP76 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV100042928; called by muse, mutect2, varscan2
- CERS3 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99432499; called by muse, mutect2, varscan2
- COL14A1 | c.4143G>T p.K1381N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV52855090, COSV99920165; called by muse, mutect2, varscan2
- COL24A1 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV100993801; called by muse, mutect2, varscan2
- CPSF1 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV100574705; called by muse, mutect2, varscan2
- CTNNAL1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100336679; called by muse, mutect2, varscan2
- DCAF4 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100611132; called by muse, mutect2, varscan2
- DHX36 | c.2114T>A p.M705K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100273825, COSV57674335; called by muse, mutect2, varscan2
- DNAH10 | c.10700G>A p.R3567Q (on ENST00000409039; = p.R3506Q on NM_207437.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs375217171; called by muse, mutect2, varscan2
- DPRX | c.422C>G p.A141G | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs898877644, COSV100934110; called by muse, mutect2, varscan2
- DPYSL5 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99982644; called by muse, mutect2, varscan2
- EIF2AK1 | c.400A>T p.R134* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV99552176; called by muse, mutect2, varscan2
- EVPL | c.3252G>C p.K1084N | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV101440957; called by muse, mutect2, varscan2
- EVPL | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101440958; called by muse, mutect2
- EYA3 | c.498A>T p.Q166H | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.371); catalogued as COSV100870280; called by muse, mutect2
- FRMPD1 | c.2329A>G p.K777E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100899606; called by muse, mutect2, varscan2
- GABRA1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV50116075, COSV99196161; called by muse, mutect2, varscan2
- GALNT9 | c.1447G>A p.E483K (on ENST00000328957 / NM_001122636.2; = p.E117K on NM_021808.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.049); catalogued as COSV61104109; called by muse, mutect2
- GGCX | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV99290123; called by muse, mutect2, varscan2
- GLB1L | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV99850794; called by muse, mutect2, varscan2
- GNPAT | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100791675; called by muse, mutect2, varscan2
- GTF3C3 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.475); catalogued as COSV99826881; called by muse, mutect2, varscan2
- GTF3C4 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV100936060; called by muse, mutect2, varscan2
- H2AW | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100797307; called by muse, mutect2, varscan2
- HMCN1 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV54907308, COSV99633548; called by muse, mutect2, varscan2
- IFT122 | c.1147+2T>A p.X383_splice (on ENST00000348417 / NM_052989.3; = p.X324_splice on NM_018262.4) | Splice Site (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99959673; called by muse, mutect2, varscan2
- IFT172 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs148237432; called by muse, mutect2, varscan2
- IGKV1D-42 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs775342781; called by muse, mutect2, varscan2
- ITPRID2 | c.2377C>G p.Q793E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100238593; called by muse, mutect2, varscan2
- KLF1 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322471; called by muse, mutect2, varscan2
- LRP1B | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV101259174; called by muse, mutect2, varscan2
- LRSAM1 | c.825A>C p.E275D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100031785; called by muse, mutect2, varscan2
- MED10 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs773128691, COSV99740366; called by muse, mutect2, varscan2
- MPP2 | c.1163G>A p.R388H (on ENST00000461854 / NM_001278372.2; = p.R364H on NM_005374.5) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199968039, COSV52234149; called by muse, mutect2, varscan2
- MRPL4 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99460222; called by muse, mutect2, varscan2
- MYO9A | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100614050; called by muse, mutect2, varscan2
- NDRG3 | c.1037C>T p.S346F (on ENST00000349004 / NM_032013.4; = p.S334F on NM_022477.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100675435; called by muse, mutect2, varscan2
- NELL1 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs547191182, COSV54250837, COSV54315728; called by mutect2, varscan2
- NLRP5 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs775580229, COSV66766592; called by muse, mutect2, varscan2
- NPHP3 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100447219; called by muse, mutect2, varscan2
- NUFIP2 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99837598; called by muse, mutect2, varscan2
- OR2M4 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV100141436; called by muse, mutect2, varscan2
- OR4C15 | c.539G>T p.C180F (on ENST00000314644; = p.C126F on NM_001001920.2) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as rs555404830, COSV100115945, COSV58951002, COSV58954526; called by muse, mutect2, varscan2
- PEX12 | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99862197; called by muse, mutect2, varscan2
- PKHD1 | c.11930C>T p.S3977F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs761192093, COSV100945011; called by muse, mutect2, varscan2
- PLAT | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1020857645, COSV54277868, COSV99535066; called by muse, mutect2
- PPP4R1 | c.2455A>G p.T819A (on ENST00000400556 / NM_001042388.3; = p.T802A on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs957339515, COSV99553825; called by muse, mutect2, varscan2
- PRMT2 | c.666G>C p.M222I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99388786; called by muse, mutect2, varscan2
- PRTG | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV101221458, COSV66837501; called by mutect2, varscan2
- RAD50 | c.3250G>T p.E1084* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | catalogued as rs765931959, COSV54751452, COSV54753432; called by muse, mutect2, varscan2
- RARG | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV100553611; called by muse, mutect2, varscan2
- RIOK3 | c.1091A>G p.H364R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100259419; called by muse, mutect2, varscan2
- RNF111 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100789122; called by muse, mutect2, varscan2
- RPS3 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV99584427; called by muse, mutect2, varscan2
- RRAS2 | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99819172; called by muse, mutect2, varscan2
- RXFP1 | c.971+1G>C p.X324_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100314069; called by muse, mutect2, varscan2
- SERTAD3 | c.19A>T p.R7W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100475155; called by muse, mutect2
- SHC4 | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195069; called by muse, mutect2, varscan2
- SI | c.4027A>T p.I1343L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100016647; called by muse, mutect2, varscan2
- SIPA1L3 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99729916; called by muse, mutect2, varscan2
- SLAMF7 | c.871A>C p.N291H | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100833344; called by muse, mutect2, varscan2
- SLC52A1 | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99643497; called by muse, mutect2, varscan2
- SMG1 | c.7471A>T p.S2491C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV101246653; called by muse, mutect2, varscan2
- SPANXN4 | c.49T>A p.C17S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.849); catalogued as COSV100980999; called by muse, mutect2
- TAS1R2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100946311; called by muse, mutect2
- TMEM87A | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100213303; called by muse, mutect2, varscan2
- TNR | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV54876723, COSV54877373, COSV99690820; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TRAPPC9 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV101228302; called by muse, mutect2, varscan2
- TRIM42 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.103); catalogued as COSV99648669; called by muse, mutect2, varscan2
- TSLP | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV100789207; called by muse, mutect2, varscan2
- UTRN | c.4154C>T p.S1385L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV62347924; called by muse, mutect2, varscan2
- VANGL2 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100925594, COSV63604461; called by muse, mutect2, varscan2
- WAPL | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100077138; called by muse, mutect2, varscan2
- WTAP | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100603393; called by muse, mutect2, varscan2
- WWOX | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775926660, COSV101283465; called by muse, mutect2, varscan2
- ZFHX4 | c.10403C>G p.S3468* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV50676904, COSV99266061; called by muse, mutect2, varscan2
- ZFR | c.1906A>G p.M636V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99416336; called by muse, mutect2, varscan2
- ZMAT2 | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99218149; called by muse, mutect2, varscan2
- ZNF425 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100955565; called by muse, mutect2, varscan2
- ZNF682 | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV100653326; called by muse, mutect2, varscan2
- ABHD17B | c.294dup p.G99Wfs*5 | Frame Shift Ins (INS) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- CTC1 | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2
- FAT1 | c.4331dup p.K1445Qfs*7 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- KAT5 | c.455_457del p.E152del | In Frame Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- KRTAP1-3 | c.366dup p.C123Lfs*42 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- RIPK4 | c.637_638insGATTA p.I213Rfs*24 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- SRPRA | c.1508dup p.M503Ifs*9 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- STK4 | c.522dup p.T175Yfs*45 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- WEE1 | c.1755del p.N585Kfs*53 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- ATXN10 | c.1254G>C p.V418= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV53299740, COSV99426622; called by muse, mutect2, varscan2
- BARD1 | c.1737A>G p.S579= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs876659896, COSV99639476; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL8A1 | c.1923C>T p.N641= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs773581749, COSV53729554; called by muse, mutect2, varscan2
- DISP3 | c.2208C>T p.F736= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs746847290, COSV53825162; called by mutect2, varscan2
- FOSB | c.300G>A p.P100= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs751752030, COSV62278672; called by muse, mutect2
- GPM6A | c.822C>G p.L274= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV99704981; called by muse, mutect2, varscan2
- HAPLN3 | c.960C>T p.S320= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs201017497; called by muse, mutect2, varscan2
- HIPK1 | c.3429A>G p.A1143= (on ENST00000369558 / NM_001369806.1; = p.A749= on NM_181358.2) | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100479489; called by muse, mutect2, varscan2
- KDM1A | c.774T>C p.R258= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV100752755; called by muse, mutect2, varscan2
- KIAA1109 | c.39A>C p.I13= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- LIN54 | c.1551G>A p.S517= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as rs369299740; called by muse, mutect2, varscan2
- LY6D | c.144G>T p.T48= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100009336, COSV56660937; called by muse, mutect2, varscan2
- MRPL4 | c.544C>T p.L182= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99460227; called by muse, mutect2, varscan2
- MUC2 | c.1209T>C p.D403= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1310208410; called by muse, mutect2, varscan2
- NLRP10 | c.867C>T p.L289= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV60779651; called by muse, mutect2, varscan2
- NOP58 | c.564C>T p.G188= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99970764; called by muse, mutect2, varscan2
- NUGGC | c.1041G>A p.R347= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58432926, COSV58436610; called by muse, mutect2, varscan2
- OR10X1 | c.690C>A p.I230= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100936702, COSV63768042; called by muse, mutect2, varscan2
- P2RY1 | c.183A>G p.V61= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV59310143; called by muse, mutect2, varscan2
- PCDHA10 | c.1248G>A p.R416= | Silent (SNP) | VAF 60/164 reads (37%) | catalogued as COSV100252868; called by muse, mutect2, varscan2
- PCDHA13 | c.63C>T p.L21= | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as COSV56532382; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PFKFB3 | c.207C>T p.F69= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1564627730, COSV57989098; called by muse, mutect2, varscan2
- PLEKHG4 | c.1155A>G p.L385= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100846519; called by muse, mutect2, varscan2
- PRC1 | c.1332G>A p.E444= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as COSV100727191, COSV62694998; called by muse, mutect2, varscan2
- PRR30 | c.942C>T p.P314= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs369715723; called by muse, mutect2, varscan2
- RANBP10 | c.450C>T p.F150= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100449439; called by muse, mutect2, varscan2
- RGS7BP | c.234G>T p.S78= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100471139; called by muse, mutect2, varscan2
- SLC7A14 | c.1101C>T p.D367= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs751620264, COSV51587461; called by muse, mutect2, varscan2
- SLC8B1 | c.927C>T p.L309= | Silent (SNP) | VAF 48/251 reads (19%) | catalogued as COSV99176801; called by muse, mutect2, varscan2
- SPRY3 | c.237G>A p.L79= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100249478; called by muse, mutect2, varscan2
- SYF2 | c.684A>G p.K228= | Silent (SNP) | VAF 22/239 reads (9%) | catalogued as COSV99360113; called by muse, mutect2
- TBPL1 | c.288A>T p.I96= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51600500, COSV99260359; called by muse, mutect2, varscan2
- TNN | c.2289C>A p.V763= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99512615; called by muse, mutect2, varscan2
- TP53 | c.942C>T p.S314= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99433274; called by muse, varscan2
- USP5 | c.738C>G p.V246= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV99978949; called by muse, mutect2, varscan2
- VCL | c.1314A>T p.I438= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99281163; called by muse, mutect2, varscan2
- ZDHHC20 | c.105G>A p.V35= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100203654; called by muse, mutect2, varscan2
- ZNF318 | c.4416C>T p.I1472= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1214112437, COSV100546418, COSV100546588; called by muse, mutect2, varscan2
- ZNF622 | c.39C>T p.F13= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV58074043; called by muse, mutect2
- ZNF658 | c.1086C>A p.L362= | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as rs758093302; called by muse, mutect2, varscan2
- FAM27E5 | n.449G>C | RNA (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- NRP1 | c.1759+1286G>A | Intron (SNP) | VAF 12/57 reads (21%) | catalogued as rs1433646782, COSV55166378; called by muse, mutect2, varscan2
